Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LT, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LT-01A (Primary Tumor).

ICD-O-3
Path Carcinoma, Oxyphilic 8290/3
CCCF Carcinoma, Adrenal Cortical 8370/3
Site: ① Adrenal Gland Cortex C74.0
JED 2/6/13

Procedure: Left adrenalectomy and left nephrectomy

Gross description: Weight of both adrenal and kidney = 1060g. Tumor measures 14 x 13cm.

Diagnosis: Carcinoma of adrenal with oxyphilic features (based on Bisceglia et al).
Weiss score = 8. Thrombus in renal vein. No lymph node metastasis. Peritoneal fluid contains no malignant cells.

Criteria	6/1/13	Yes	No
Malignant Discrepancy			
ICD-O Discrepancy			
Reviewed Initials:			

Source: NCI Genomic Data Commons file 04790c46-7a73-4d5f-9994-25eecbca9531 (TCGA-OR-A5LT.6C9B7DE2-682F-4F4A-8879-159F9989C40C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).